FM case AD11720 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/8b9abb66-efa5-48ea-90e6-a97ba6df1ca9

Male, 66.0 years: Large cell neuroendocrine carcinoma (ICD-O-3 8013/3) of the lung; metastasis biopsied or resected from the adrenal gland. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
